Gene-level copy-number profile of tumor specimen ALCH-B1VA-TTP1-A from ALCHEMIST case ALCH-B1VA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 43.3 years (15,829 days).
Specimen ALCH-B1VA-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b0d95e62-4fb7-4b90-acf6-f0420673184d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1VA-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/7fafbdff-29f8-415b-8855-892df56c185a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 528; copy number 1: 9,447; copy number 2: 46,005; copy number 3: 1,369; copy number 4: 1,537; copy number 5: 4; copy number 6: 6; copy number 9: 2; copy number 12: 3; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,159,840–90,160,335, 1 gene (within-gene range 0–2): IGKV1D-12.
- chr6:51,975,673–51,975,959, 1 gene (within-gene range 0–1): RN7SL580P.
- chr8:125,648,327–126,008,930, 1 gene (within-gene range 0–2): AC016074.2.
- chr8:125,859,721–126,292,788, 2 genes (within-gene range 0–2): LINC00861, RNU6-442P.
- chr9:117,704,157–118,072,314, 1 gene (within-gene range 0–1): AL160272.2.
- chr9:117,759,455–117,879,988, 1 gene (within-gene range 0–1): AL160272.1.
- chr12:97,272,692–97,276,209, 1 gene: LINC02409.
- chr18:45,423,764–45,483,218, 1 gene (within-gene range 0–1): SLC14A2-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,319,625–89,600,680, 3 genes, copy number 6: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr2:89,872,463–89,887,247, 3 genes, copy number 5: IGKV2D-38, IGKV1D-37, IGKV2D-36.
- chr9:39,886,861–39,892,895, 3 genes, copy number 6: RN7SL763P, SNORA70, CR769767.1.
- chr9:64,817,870–64,836,341, 1 gene, copy number 9: AL359955.1.
- chr9:65,189,995–65,285,209, 4 genes, copy number 12–14: BMS1P12, AL512605.1, AL512605.2, FOXD4L5.
- chr14:18,395,626–18,419,273, 2 genes, copy number 5–9: CR383658.2, BNIP3P6.

Autosomal genes at a single copy (total copy number 1): 7,133. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
